Somatic mutation profile of tumor specimen PCProject_0193_T1A_WES (aliquot PCProject_0193_T1A_WES_1) from CMI case PCProject_0193, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.5 years (23,921 days).
Specimen PCProject_0193_T1A_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01b2865c-13f1-4195-9789-094fb9677e1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0193_SALIVA (DNA), aliquot PCProject_0193_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62b94af6-c031-4c39-93dd-b7ed3b47f037

The open-access MAF lists 49 somatic variants for this specimen: 32 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 12, Intron 4, Frame Shift Del 3, Nonsense Mutation 2, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 76/260 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: pathogenic / likely pathogenic /  other; called by muse, mutect2, varscan2
- CYP11B1 | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1447069098, CM097789; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.5878G>A p.A1960T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as rs532727754; called by mutect2, varscan2
- ANO10 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 23/95 reads (24%) | catalogued as rs1314514015; called by muse, mutect2, varscan2
- ATM | c.6805C>T p.Q2269* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as COSV53754260; called by muse, mutect2, varscan2
- ATM | c.7294del p.I2432Ffs*8 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as CM035636; called by mutect2, pindel, varscan2
- CBX4 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 70/252 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs1461128997; called by muse, varscan2
- CDR2 | c.1063G>C p.A355P | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV51676032; called by muse, mutect2, varscan2
- FCGBP | c.5308G>C p.G1770R | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as rs1257013860; called by muse, mutect2
- FOLH1 | c.1786G>T p.D596Y | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV57051515; called by muse, varscan2
- GHRHR | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 28/285 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs774281185, CM030450; called by muse, mutect2, varscan2
- MUC4 | c.11991C>G p.H3997Q | Missense Mutation (SNP) | VAF 23/284 reads (8%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.065); catalogued as rs113130007, COSV57770630; called by muse, varscan2
- NWD1 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs777000586; called by muse, mutect2, varscan2
- PDYN | c.182G>A p.R61K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.03); catalogued as COSV54102435, COSV99453465; called by muse, mutect2, varscan2
- PDZRN3 | c.659T>C p.F220S | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV55212788; called by muse, mutect2, varscan2
- SPTB | c.4247G>A p.R1416Q | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.067); catalogued as rs777704033, COSV67633410; called by muse, mutect2, varscan2
- VPS13B | c.2056C>T p.R686W | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs148047632; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD3 | c.2900G>T p.R967I | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FOLH1 | c.1854T>G p.H618Q | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, varscan2
- GPR137B | c.286T>G p.F96V | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GPR179 | c.1249G>A p.V417M (on ENST00000621958; = p.V416M on NM_001004334.4) | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- GRIK1 | c.2750A>C p.K917T (on ENST00000327783 / NM_001330994.2; = p.K873T on NM_175611.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- HELQ | c.1379T>G p.V460G | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- INCA1 | c.277_281del p.K93Efs*52 (on ENST00000574617 / NM_001167986.1; = p.K78Efs*52 on NM_213726.2) | Frame Shift Del (DEL) | VAF 12/139 reads (9%) | called by mutect2, pindel
- KBTBD11 | c.845A>C p.D282A | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2
- KMT2A | c.9173A>G p.Q3058R | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); called by muse, mutect2
- MARS2 | c.1015T>A p.S339T | Missense Mutation (SNP) | VAF 45/213 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MNX1 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.397); called by mutect2, varscan2
- PTPRD | c.3153A>T p.K1051N | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.184); called by mutect2, varscan2
- RASA1 | c.446del p.G149Afs*25 | Frame Shift Del (DEL) | VAF 48/184 reads (26%) | called by mutect2, pindel, varscan2
- SLC30A8 | c.536T>A p.I179N | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SPOP | c.79-2A>C p.X27_splice | Splice Site (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- ARHGEF3 | c.630C>G p.S210= | Silent (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- ARL4D | c.303G>T p.V101= | Silent (SNP) | VAF 37/203 reads (18%) | called by muse, mutect2, varscan2
- AVIL | c.1464C>A p.I488= | Silent (SNP) | VAF 89/212 reads (42%) | catalogued as COSV57684039; called by muse, mutect2, varscan2
- CATSPERB | c.3324G>C p.L1108= | Silent (SNP) | VAF 12/28 reads (43%) | called by muse, varscan2
- CRY2 | c.684C>A p.V228= | Silent (SNP) | VAF 44/141 reads (31%) | called by muse, mutect2, varscan2
- EPB41L2 | c.981C>G p.P327= | Silent (SNP) | VAF 39/168 reads (23%) | called by muse, mutect2, varscan2
- ITIH3 | c.783C>T p.N261= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs761256610; called by mutect2, varscan2
- LRRN4CL | c.465C>T p.A155= | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as COSV54016489; called by muse, mutect2, varscan2
- PLEKHG4 | c.3129C>A p.S1043= | Silent (SNP) | VAF 27/190 reads (14%) | called by muse, mutect2, varscan2
- PPIB | c.9C>A p.R3= | Silent (SNP) | VAF 46/388 reads (12%) | called by muse, mutect2, varscan2
- TPCN2 | c.2049C>T p.V683= | Silent (SNP) | VAF 81/573 reads (14%) | called by muse, varscan2
- ZNF205 | c.864C>T p.G288= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as rs768630476; called by muse, mutect2, varscan2
- ABHD18 | c.699+1034G>T | Intron (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- AK9 | c.3633+13del | Intron (DEL) | VAF 10/76 reads (13%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
- RRP7A | c.217-139A>C | Intron (SNP) | VAF 50/144 reads (35%) | called by muse, mutect2, varscan2
- SFXN5 | c.945+4063C>T | Intron (SNP) | VAF 12/68 reads (18%) | called by muse, mutect2, varscan2
- SNORD115-31 | n.30T>A | RNA (SNP) | VAF 27/111 reads (24%) | called by muse, mutect2, varscan2
